Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72H, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72H-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site R Kidney NOS
C64.9
JW 8/9/13

Diagnosis:

Kidney, right, nephrectomy

Histologic tumor type/subtype: Chromophobe renal cell carcinoma

Sarcomatoid features: None identified

Histologic grade (if applicable): Fuhrman grade 4

Tumor size (greatest dimension): 5.2 cm

Tumor focality: Unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: Negative

Gerota' s fascia: Negative

Renal sinus: Positive; microscopic (slide A9)

Major veins (renal vein or segmental branches, IVC): Negative

Ureter: Negative

Venous (large vessel): Negative

Lymphatic (small vessel): Negative

Histologic assessment of surgical margins:

Gerota' s fascia (nephrectomy): Negative

Renal vein (nephrectomy): Negative

Ureter (nephrectomy): Negative

Adrenal gland: Negative for carcinoma

Lymph nodes: Not applicable

Other significant findings: None identified

AJCC Staging:

pT3a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

[page 2 of 3]
Comment:

The malignant cells have high grade nuclei and eosinophilic cytoplasm with large vacuolated cells identified adjacent to blood vessels. The malignant cells are immunoreactive for CK7 and E-cadherin but negative for CD10. The staining pattern for CD117 demonstrates background staining and is non-contributory. The morphology and immunophenotype are consistent with chromophobe renal cell carcinoma.

Clinical History:

-year-old male with right renal mass.

Gross Description:

Specimen fixation: Received fresh and later placed in formalin.

Type of specimen: Radical nephrectomy

Side of specimen: Per requisition, right

Size and weight of specimen: The overall size of the specimen is 20.9 x 14.0 x 5.5 cm . The kidney measures 12.5 x 8.0 x 4.5 cm. The overall weight of the specimen is 450 grams. The weight of the kidney (formalin fixed and perinephric fat removed) is 230 grams.

Orientation: N/A. The perinephric fat is inked blue at the time of triage.

Presence/absence of adrenal gland: There is a 1.6 cm long staple line within the superior aspect and within the staple line there is a 0.4 cm in greatest dimension piece of yellow/orange tissue (may represent adrenal tissue).

Tumor site: Mid pole, lateral

Tumor description: The tumor has a tan/red soft solid well-circumscribed cut surface.

Tumor size: 5.2 x 5.0 x 4.5 cm

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Confined

Extent of invasion:

Perirenal adipose tissue: Does not involve

[page 3 of 3]
Gerota' s fascia: Does not involve

Renal vein: Does not involve (1.1 cm in diameter)

Ureter: Does not involve (6 cm in length x 0.3 cm in diameter)

Renal Sinus: Does not involve

Pelvicaliceal: Does not involve

Adrenal: Does not involve

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: The remainder of the cortical tissue is red/brown, firm with a distinct cortical medullary junction.

Hilar lymph nodes: No lymph nodes are palpated.

Other significant findings: None

Tissue submitted for special investigations: Yes. Tumor and normal are submitted to tissue procurement.

Digital picture:

Block Summary:

- A1 - Vein artery and ureter margins, en face
- A2 - Tumor with renal capsule
- A3 - Tumor and adjacent cortical tissue
- A4 - Tumor and pelvis
- A5 - Additional section of tumor
- A6 - Apparent adrenal tissue
- A7 - Kidney away from tumor
- A8-A9 - Additional sections of renal sinus fat

Source: NCI Genomic Data Commons file f28bbb3b-de11-4d68-9fb6-cba35a52d2eb (TCGA-UW-A72H.96CB2C5D-A95D-42B0-B42C-3A3C26B6451F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).